Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMW, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMW-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Collected:
Ordered by:

Location:

DIAGNOSIS:

RADICAL CYSTECTOMY, TOTAL ABDOMINAL HYSTERECTOMY WITH BILATERAL
SALPINGO-OOPHORECTOMY, BILATERAL PELVIC LYMPH NODE DISSECTION, ILEAL CONDUIT
DIVERSION TO SKIN AND GASTROSTOMY TUBE PLACEMENT:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN HYDROURETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER / UTERUS / BILATERAL OVARIES AND FALLOPIAN TUBES (C):

BLADDER:

- INVASIVE POORLY DIFFERENTIATED UROTHELIAL CARCINOMA (3.5 X 2.7 X 1.6 CM),
GRADE 4/4, EXTENDING INTO DEEP MUSCULARIS PROPRIA OF POSTERIOR WALL AND
TRIGONE TO ABUT WITHOUT INVOLVING PERIVESICAL SOFT TISSUE
- CARCINOMA INVOLVING AND PARTIALLY OBSTRUCTING RIGHT URETEROVESICAL
JUNCTION
- RANDOM BLADDER MUCOSA REMOTE FROM MASS, NO UROTHELIAL DYSPLASIA OR
MALIGNANCY
- RIGHT DISTAL HYDROURETER EXHIBITING SEPARATE INVASIVE POORLY
DIFFERENTIATED UROTHELIAL CARCINOMA (0.8 X 0.6 X 0.5 CM), GRADE 4/4, EXTENDING
THROUGH MUSCULARIS PROPRIA OF URETER WALL TO INVOLVE PERIURETERAL SOFT
TISSUE
- URETHRA, NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED
- RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY

UTERUS:

- CERVIX, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- ENDOMETRIUM, ATROPHY
- MYOMETRIUM, BENIGN INTRAMURAL LEIOMYOMAS
- SEROSA, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- NO DYSPLASIA, ATYPIA OR MALIGNANCY IDENTIFIED

BILATERAL FALLOPIAN TUBES AND OVARIES:

- RIGHT AND LEFT OVARIES, ATROPHY WITH BENIGN PHYSIOLOGIC CHANGES
- RIGHT AND LEFT FALLOPIAN TUBES, NO SIGNIFICANT HISTOPATHOLOGIC CHANGE
- NO ATYPICAL OR MALIGNANT ELEMENTS IDENTIFIED

RIGHT PARA CAVAL LYMPH NODES (D):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT COMMON ILIAC LYMPH NODES (E)

- NO MALIGNANCY IDENTIFIED IN 14 LYMPH NODES EXAMINED (0/14)

LEFT COMMON ILIAC LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN 17 LYMPH NODES EXAMINED (0/17)

RIGHT NODE OF CLOQUET (G):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

ICD 6-3
Carcinoma, urothelial NOS 8/28/13
Site Bladder NOS C67.9
JW 3/26/14

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

RIGHT EXTERNAL ILIAC LYMPH NODES (H):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (I):

- NO MALIGNANCY IDENTIFIED IN 15 LYMPH NODES EXAMINED (0/15)

LEFT NODE OF CLOQUET (J):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT EXTERNAL ILIAC LYMPH NODES (K):

- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (L):

- NO MALIGNANCY IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

RIGHT PRESACRAL LYMPH NODES (M):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

PRESACRAL LYMPH NODES (N):

- PARAGANGLION PRESENT
- NO LYMPH NODES OR MALIGNANCY IDENTIFIED (0/0) [ENTIRELY EMBEDDED]

LEFT PRESACRAL LYMPH NODES (O):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1) [ENTIRELY EMBEDDED]

LEFT PROXIMAL URETER [MARGIN] (P):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER [MARGIN] (Q):

- BENIGN HYDROURETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

SUMMARY OF LYMPH NODES:

- NO MALIGNANCY IDENTIFIED IN TOTAL OF 70 LYMPH NODES EXAMINED (0/70)

PATHOLOGIC TNM STAGE: BLADDER pT2bN0MX

URETER pT3N0MX

Electronically signed by
Verified:

COMMENT:

Representative sections of invasive carcinoma from both the bladder and ureter are submitted for p53 assay by immunohistochemistry, results of which will be issued in an addendum report.

SPECIMEN SOURCE:

- A: "Right distal ureter F/S"
- B: "Left distal ureter F/S"
- C: "Bladder/Uterus/Bilateral ovaries + Fallopian tubes"

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

D: "R. para caval L. nodes"
E: "R. common iliac L. nodes"
F: "L. common iliac L. nodes"
G: "R. node of cloquet"
H: "R. external iliac L. nodes"
I: "R. obturator/hypogastric L. nodes"
J: "L. node of cloquet"
K: "L. external iliac L. node"
L: "L. obturator/hypogastric L. node"
M: "R. presciatic L. nodes"
N: "Pre sacral L. nodes"
O: "Left pre sciatic lymph nodes"
P: "L. proximal ureter (margin)"
Q: "R. proximal ureter (margin)"

CLINICAL INFORMATION:

Pre-op Dx: Bladder cancer

Post-op Dx: Same

GROSS EXAMINATION:

AFS: The specimen is received fresh from the O.R. and labeled "Right distal ureter F/S". It consists of a segment of pink-tan ureter weighing less than 1 gram and measuring 0.3 cm in length x 0.5 cm in diameter. The specimen is entirely submitted for frozen section in AFS.

BFS: The specimen is received fresh from the O.R. and labeled "Left distal ureter F/S". It consists of a segment of pink-tan ureter weighing less than 1 gram and measuring 0.3 cm in length x 0.3 cm in diameter. The specimen is entirely submitted for frozen section in BFS.

C: The specimen is received fresh from the O.R. and labeled "Bladder/Uterus/Bilateral ovaries + Fallopian tubes". It consists of a composite resection of bladder, uterus and bilateral ovaries and fallopian tubes measuring overall 23 x 19 x 5 cm. A flap of peritoneum is identified measuring 23 x 16 x less than 0.1 cm. It is smooth and glistening. The bladder itself measures 6 x 5 x 2.5 cm. The resection margins are inked black. The bladder is opened along its anterior urethra and bladder wall. The uninvolved bladder wall measures 0.9 cm in thickness. Opening the bladder reveals a nodular mass with a granular surface on the posterior wall involving the trigone and right ureterovesical junction measuring 3.5 x 2.7 x 1.6 cm. This mass is located 0.3 cm from the left ureterovesical junction and penetrates the posterior wall to a depth of 0.5 cm where it abuts the perivesical fat without grossly extending into it. The right and left ureterovesical junctions are identified. The right ureterovesical junction is involved by the mass and is partially obstructed, while the mass comes within 0.3 cm of the left ureterovesical junction without actually involving it. The right attached ureter is dilated and measures 5.5 cm in length x 1.3 cm in circumference and the left attached ureter measures 5.5 cm in length x 0.5 cm in circumference. A dark red well circumscribed sessile mass 0.8 x 0.6 x 0.5 cm is present in the distal most right ureter located 0.4 cm from the ureterovesical junction. This ureteral mass is separate and distinct from the mass in the bladder. The uterus measures overall 6 x 4 x 2.5 cm. The serosa is smooth and the ectocervix measures 3.5 cm in diameter with a 0.5 cm parous cervical os. The right ovary measures 2.5 x 1 x 0.6 cm. The associated fallopian tube is 17 cm long with a diameter ranging from 0.3 to 0.5 cm. The left ovary measures 2.5 x 1.4 x 0.4 cm and is congruent with an 9 cm long x 0.3 to 0.4 cm diameter fallopian tube. Both tubes and ovaries are unremarkable. The endometrium thickness averages 0.2 cm and the endomyometrial wall thickness averages 1.1 cm. Multiple leiomyomas are present measuring up to 0.6 cm in diameter within the myometrium wall. The cervix and the endocervical mucosa are unremarkable. Representative sections are submitted in 24 cassettes.

[page 4 of 6]
Collected:

Ordered by:

Location:

D: The specimen is received in formalin and labeled "R. para caval L. nodes". It consists of yellow-tan lobulated adipose tissue weighing 3 grams and measuring 3 x 2 x 1.5 cm. Two lymph nodes are identified measuring 0.7 to 0.9 cm in greatest dimension. The specimen is totally embedded in three cassettes.

E: The specimen is received in formalin and labeled "R. common iliac L. nodes". It consists of multiple yellow-tan lobulated adipose tissue segments weighing 10 grams and measuring in aggregate 5 x 3 x 2.5 cm. Multiple lymph nodes are identified measuring 0.3 to 1 cm in greatest dimension. The specimen is totally embedded in nine cassettes.

F: The specimen is received in formalin and labeled "L. common iliac L. nodes". It consists of multiple yellow-tan lobulated adipose tissue fragments weighing 6 grams and measuring in aggregate 5 x 3 x 1 cm. Multiple lymph nodes are identified measuring 0.2 to 0.5 cm in greatest dimension. The specimen is totally embedded in six cassettes.

G: The specimen is received in formalin and labeled "R. node of cloquet". It consists of a single yellow-tan lobulated adipose tissue segment measuring 1.5 x 0.5 x 0.5 cm. A single lymph node is identified measuring 1.3 x 0.5 x 0.5 cm. The specimen is bisected and totally embedded in one cassette.

H: The specimen is received in formalin and labeled "R. external iliac L. nodes". It consists of yellow-tan lobulated adipose tissue weighing 3 grams and measuring 3 x 1 x 1 cm. A single lymph node is identified measuring 1 x 0.2 x 0.2 cm. The specimen is totally embedded in two cassettes.

I: The specimen is received in formalin and labeled "R. obturator/hypogastric L. nodes". It consists of multiple yellow-tan lobulated adipose tissue segments weighing 12 grams measuring measuring in aggregate 8 x 3 x 2 cm. Multiple lymph nodes are identified measuring 0.1 to 2 cm. The specimen is totally embedded in ten cassettes.

J: The specimen is received in formalin and labeled "L. node of cloquet". It consists of yellow-tan lobulated adipose tissue fragment weighing less than 1 gram and measuring 1 x 0.6 x 0.6 cm. Two lymph nodes are identified measuring 0.4 to 0.5 cm in greatest dimension. The specimen is totally embedded in one cassette.

K: The specimen is received in formalin and labeled "L. external iliac L. node". It consists of yellow-tan lobulated adipose tissue weighing 3 grams and measuring 3 x 2 x 2 cm. Multiple lymph nodes are identified measuring 0.2 to 0.6 cm. The specimen is totally embedded in three cassette.

L: The specimen is received in formalin and labeled "L. obturator/hypogastric L. node". It consists of multiple yellow-tan lobulated adipose tissue fragments weighing 9 grams and measuring in aggregate 6 x 5 x 2 cm. The specimen is totally embedded in ten cassettes.

M: The specimen is received in formalin and labeled "R. presciatic L. nodes". It consists of yellow-tan lobulated adipose tissue weighing less than 1 gram and measuring 1.5 x 1 x 0.4 cm. Three possible lymph nodes are identified measuring 0.2 to 0.3 cm. The specimen is totally embedded in one cassette.

N: The specimen is received in formalin and labeled "Pre sacral L. nodes". It consists of a portion of yellow-tan lobulation adipose tissue weighing 6 grams and measuring 6 x 3 x 0.5 cm. No definite lymph nodes are identified within this adipose tissue. The specimen is totally embedded in nine cassettes.

O: The specimen is received in formalin and labeled "Left pre sciatic lymph

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Collected:

Ordered by:

Location:

nodes". It consists of yellow-tan lobulated adipose tissue weighing less than 1 gram and measuring 1 x 1 x 0.5 cm. Grossly, no lymph node is identified. The specimen is totally embedded in one cassette.

P: The specimen is received in formalin and labeled "L. proximal ureter (margin)". It consists of a dilated pink-tan segment of ureter weighing less than 1 gram and measuring 1.5 cm in length x 0.5 cm in diameter. The specimen is serially sectioned and totally embedded in one cassette.

Q The specimen is received in formalin and labeled: "R. proximal ureter (margin)". It consists of a dilated pink-tan segment of ureter weighing less than 1 gram and measuring 1.5 cm in length x 0.7 cm in diameter. The specimen is serially sectioned and totally embedded in one cassette.

SECTIONS:

AFS: right distal ureter; frozen section
BFS: left distal ureter, frozen section
C1: bladder/uterus/bilateral ovaries + fallopian tubes; urethral margin
C2: anterior bladder wall
C3: right lateral bladder wall
C4: dome of bladder
C5: posterior bladder wall
C6: left lateral bladder wall
C7: left ureterovesical junction with tumor and left ureter
C8: urethra with tumor
C9: lower bladder neck and urethra
C10-12: full thickness tumor
C13: right ureterovesical junction
C14-15: right ureter lesion
C16-17: anterior cervix
C18: posterior cervix
C19: posterior lower uterine segment
C20: endomyometrium
C21: right ovary and oviduct
C22: left ovary and oviduct
C23: right perivesical soft tissue for possible lymph nodes
C24: left perivesical soft tissue for possible lymph nodes
D1-3: right para caval lymph nodes
E1-9: right common iliac lymph nodes
F1-6: left common iliac lymph nodes
G: right node of Cloquet, bisected
H1-2: right external iliac lymph nodes
I1-10: right obturator/hypogastric lymph nodes
J: left node of Cloquet
K1-3: left external iliac lymph node
L1-10: left obturator/hypogastric lymph node
M: right presciatic lymph nodes
N1-9: pre sacral lymph nodes
O: left pre sciatic lymph nodes
P: left proximal ureter (margin)
Q: right proximal ureter (margin)

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter
- no high grade atypia or tumor identified

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

BFS: Left distal ureter
- no high grade atypia or tumor identified

MICROSCOPIC EXAMINATION:

A-Q: See final microscopic-diagnosis.

Source: NCI Genomic Data Commons file d15e50e2-320c-4270-bfba-d48077b80cc6 (TCGA-XF-AAMW.F763F16E-C76C-4A58-9096-8B19B9825C9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).